Somatic mutation profile of tumor specimen C3L-02661-01 (aliquot CPT0192380006) from CPTAC case C3L-02661, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 59.2 years (21,632 days).
Specimen C3L-02661-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8733a439-0134-459c-a708-f4be61b8ac9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02661-31 (Blood Derived Normal), aliquot CPT0192520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16ec15b1-f587-4d97-b89f-237c06c65ab3

The open-access MAF lists 597 somatic variants for this specimen: 393 protein-altering or splice-affecting, 129 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 334, Silent 129, Intron 38, Nonsense Mutation 34, RNA 13, Splice Site 11, 5'UTR 11, Frame Shift Del 7, 3'UTR 6, 5'Flank 4, 3'Flank 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 72/195 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RYR1 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 39/447 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs118192173, CM064209, COSV62102591; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397379611; called by muse, mutect2
- ABCB8 | c.1921G>T p.A641S (on ENST00000297504 / NM_001282291.2; = p.A624S on NM_007188.5) | Missense Mutation (SNP) | VAF 85/590 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502560; called by muse, mutect2, varscan2
- AC011455.2 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 130/751 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99671400; called by muse, mutect2, varscan2
- ACAN | c.2268G>T p.G756= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as rs1244624727; called by muse, mutect2, varscan2
- AIMP1 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100786123; called by muse, mutect2, varscan2
- AKAP13 | c.4186A>G p.I1396V | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs759760018, COSV100773769; called by muse, mutect2, varscan2
- AMY2A | c.599A>G p.H200R | Missense Mutation (SNP) | VAF 102/847 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753363892; called by muse, mutect2, varscan2
- ANO7 | c.1209G>T p.W403C (on ENST00000274979; = p.W349C on NM_001370694.2) | Missense Mutation (SNP) | VAF 95/379 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51469083, COSV51472275; called by muse, mutect2, varscan2
- ARHGEF11 | c.4388C>T p.P1463L | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1204729168; called by muse, mutect2, varscan2
- ATF7IP | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 57/265 reads (22%) | catalogued as COSV53768414; called by muse, mutect2, varscan2
- C16orf78 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 26/211 reads (12%) | catalogued as COSV54556148; called by muse, mutect2, varscan2
- CALD1 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.017); catalogued as rs1370680921; called by muse, varscan2
- CASR | c.2005G>A p.A669T (on ENST00000490131; = p.A746T on NM_000388.4) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs562364178, COSV56136669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN3 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 51/458 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs978191496; called by muse, mutect2, varscan2
- COL25A1 | c.975+2T>A p.X325_splice | Splice Site (SNP) | VAF 13/110 reads (12%) | catalogued as rs1433430022; called by muse, mutect2, varscan2
- COL3A1 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs773096891; called by muse, mutect2, varscan2
- COL4A5 | c.322-1G>C p.X108_splice | Splice Site (SNP) | VAF 63/185 reads (34%) | catalogued as CS991351; called by muse, mutect2, varscan2
- COL5A1 | c.3887C>T p.P1296L | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs771130127, CD001482, COSV65671587; ClinVar: uncertain significance; called by muse, mutect2
- CRISP1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100236817; called by mutect2, varscan2
- CSMD1 | c.6935C>G p.S2312C (on ENST00000520002; = p.S2311C on NM_033225.6) | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1218657794; called by muse, mutect2, varscan2
- CSMD3 | c.2248A>T p.T750S (on ENST00000297405 / NM_001363185.1; = p.T646S on NM_052900.3) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs761486643; called by muse, mutect2
- CTSL | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as COSV58247387; called by muse, mutect2, varscan2
- DCC | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 79/508 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs774695019; called by muse, mutect2, varscan2
- DIO3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63773286; called by muse, mutect2, varscan2
- DMD | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV63732575; called by muse, mutect2, varscan2
- DRD3 | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99879246; called by muse, mutect2, varscan2
- DSG4 | c.1278-1G>C p.X426_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV57397651; called by muse, mutect2, varscan2
- DYSF | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV50511340; called by muse, mutect2
- EIF2B4 | c.331G>A p.E111K (on ENST00000347454 / NM_001034116.2; = p.E110K on NM_015636.3) | Missense Mutation (SNP) | VAF 50/847 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as rs760388895, COSV52007429; called by muse, mutect2
- ELP1 | c.3024G>A p.M1008I | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs758670783; called by muse, mutect2, varscan2
- ENAM | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV68535707; called by muse, mutect2, varscan2
- FAM131B | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs756000946, COSV68125429; called by muse, mutect2, varscan2
- FAM135B | c.3725C>A p.T1242K | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99424141; called by muse, mutect2
- FAM47C | c.2423G>T p.R808L | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100792972; called by muse, mutect2, varscan2
- FAP | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51858987; called by muse, mutect2, varscan2
- FASN | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 47/437 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1372953382; called by muse, mutect2, varscan2
- FBN3 | c.2146G>C p.G716R | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV54462552; called by muse, mutect2, varscan2
- FGD5 | c.2756A>G p.H919R | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs1300541613; called by muse, mutect2, varscan2
- GABRA2 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV62920263; called by muse, varscan2
- GLP2R | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52329775; called by muse, mutect2, varscan2
- GNRHR | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs745440845; called by muse, mutect2, varscan2
- GPT2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs781284492; called by muse, mutect2, varscan2
- HCAR3 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 70/512 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV63675799; called by muse, mutect2, varscan2
- HEATR5B | c.581G>C p.R194P | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51853250; called by mutect2, varscan2
- HECW1 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.533); catalogued as rs1283391738; called by muse, mutect2, varscan2
- HMCN1 | c.7912G>A p.E2638K | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs1558194198; called by muse, mutect2, varscan2
- HTT | c.7594C>T p.R2532W | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771751572; called by muse, mutect2, varscan2
- IGF2BP3 | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1363883172; called by muse, mutect2, varscan2
- IGHV1-2 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 59/645 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs565502821; called by muse, mutect2
- IGKV1-8 | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 93/497 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as rs775105512; called by muse, mutect2, varscan2
- IL5RA | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56525582; called by muse, mutect2, varscan2
- IL6R | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 75/522 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV59816189; called by muse, mutect2, varscan2
- KIAA1549 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779444225; called by muse, mutect2, varscan2
- KIF19 | c.1359C>A p.D453E | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV63430175; called by muse, mutect2, varscan2
- KRT37 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 66/491 reads (13%) | catalogued as rs369798171, COSV99845408; called by muse, mutect2, varscan2
- KRTAP13-2 | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 29/292 reads (10%) | catalogued as COSV67762348; called by muse, mutect2, varscan2
- KRTAP7-1 | c.230dup p.S78Lfs*18 | Frame Shift Ins (INS) | VAF 22/185 reads (12%) | catalogued as rs1236134489; called by pindel, varscan2
- LAMA1 | c.1909G>T p.V637L | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.185); catalogued as COSV67534412; called by muse, mutect2, varscan2
- LRP1B | c.6013C>A p.P2005T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67224123; called by muse, mutect2
- LRRC7 | c.2783C>A p.P928Q (on ENST00000651989 / NM_001370785.2; = p.P895Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as COSV50449079; called by muse, mutect2, varscan2
- LTB4R | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866460; called by muse, mutect2, varscan2
- MDGA2 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs768977988, COSV62077697; called by muse, mutect2, varscan2
- MEI1 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs763566976; called by muse, mutect2, varscan2
- MICALL2 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs748916625; called by muse, mutect2, varscan2
- MMUT | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as CM050691; called by muse, mutect2, varscan2
- MS4A2 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99627477; called by muse, varscan2
- MTMR8 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs777944614; called by muse, mutect2
- MYH2 | c.5812A>G p.I1938V | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs769758368; called by muse, mutect2, varscan2
- NAALADL1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 28/172 reads (16%) | catalogued as rs139658894; called by muse, mutect2, varscan2
- NEMP2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 93/359 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs772426003; called by muse, mutect2, varscan2
- NISCH | c.1533C>G p.I511M | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV61901226; called by muse, mutect2, varscan2
- NOTCH2 | c.2750C>G p.A917G | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV56696687; called by muse, mutect2, varscan2
- NPAS3 | c.2306G>T p.G769V (on ENST00000356141 / NM_001164749.2; = p.G737V on NM_022123.3) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs759209493; called by muse, mutect2, varscan2
- NTRK3 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV58128024; called by muse, mutect2
- NUMBL | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 44/301 reads (15%) | catalogued as COSV53284592; called by muse, mutect2, varscan2
- OR2G2 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.26); catalogued as COSV100189957; called by muse, mutect2, varscan2
- OR2T10 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 68/543 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1281423555, COSV100393694; called by muse, mutect2, varscan2
- OR2T11 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1179244154; called by muse, mutect2, varscan2
- OR4N5 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100374137; called by muse, mutect2, varscan2
- OR52J3 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775282566; called by muse, mutect2, varscan2
- OR5B12 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1367317120, COSV100222545; called by muse, mutect2, varscan2
- OR5M3 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56567819; called by muse, mutect2
- OR6K3 | c.812C>T p.S271L (on ENST00000368146; = p.S255L on NM_001005327.2) | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.403); catalogued as rs79482939, COSV63745622, COSV63746585; called by muse, mutect2
- PALB2 | c.3307G>T p.V1103L | Missense Mutation (SNP) | VAF 79/615 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as CM118272; called by muse, mutect2, varscan2
- PAPPA | c.2535C>A p.D845E | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.487); catalogued as rs377702306, COSV60288215; called by muse, mutect2
- PCDH19 | c.1127G>C p.R376P | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55270399; called by muse, mutect2, varscan2
- PGBD2 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61400828; called by muse, mutect2, varscan2
- PINK1 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 90/713 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as CM088098, COSV58630869; called by muse, mutect2, varscan2
- PKHD1 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140458350; called by muse, mutect2, varscan2
- PLEKHG4 | c.1510-1G>C p.X504_splice | Splice Site (SNP) | VAF 19/149 reads (13%) | catalogued as COSV100846456; called by muse, mutect2, varscan2
- PLEKHH2 | c.3888A>G p.I1296M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs777558958; called by mutect2, varscan2
- PLXNA1 | c.2962G>T p.A988S | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs750473154, COSV52526375, COSV52529801; called by muse, mutect2, varscan2
- POU6F2 | c.1453C>G p.R485G | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145241880, COSV101302660; called by muse, mutect2, varscan2
- PPT1 | c.555G>T p.W185C (on ENST00000433473; = p.W186C on NM_000310.4) | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM120810; called by muse, mutect2, varscan2
- PRDM16 | c.1982G>C p.S661T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54587252; called by muse, mutect2, varscan2
- PRRT4 | c.2034C>A p.C678* | Nonsense Mutation (SNP) | VAF 27/221 reads (12%) | catalogued as rs937699925; called by muse, mutect2, varscan2
- PSMD8 | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 81/441 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs761814714; called by muse, mutect2, varscan2
- REG1A | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99286795; called by muse, mutect2, varscan2
- RHPN2 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs183236318, COSV99577974; called by muse, mutect2, varscan2
- RUNX1T1 | c.1598G>T p.R533L (on ENST00000265814 / NM_001198628.1; = p.R506L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56138227; called by muse, mutect2, varscan2
- RUNX2 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs891974332; called by muse, mutect2, varscan2
- SCG2 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs143964627, COSV100544618; called by muse, mutect2, varscan2
- SIPA1 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs1286558072; called by muse, mutect2, varscan2
- SLC4A10 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99764090; called by muse, mutect2, varscan2
- SLC4A2 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV100055324, COSV100055342; called by muse, mutect2, varscan2
- SLC6A5 | c.2391C>A p.C797* | Nonsense Mutation (SNP) | VAF 45/465 reads (10%) | catalogued as COSV54225376; called by muse, mutect2, varscan2
- SNX7 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs1018299385, COSV60272859; called by muse, mutect2
- SPATA31A1 | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 178/885 reads (20%) | catalogued as COSV66533393; called by muse, mutect2, varscan2
- SPDYE1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 185/878 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs1253408413, COSV51671424; called by muse, mutect2, varscan2
- SRCAP | c.4360C>A p.P1454T | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.356); catalogued as rs372567989; called by muse, mutect2, varscan2
- SSU72P8 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV66361273; called by muse, mutect2, varscan2
- TBX3 | c.1204G>T p.E402* (on ENST00000257566 / NM_016569.4; = p.E382* on NM_005996.4) | Nonsense Mutation (SNP) | VAF 97/603 reads (16%) | catalogued as COSV57474338; called by muse, mutect2, varscan2
- TEK | c.2254C>A p.L752I | Missense Mutation (SNP) | VAF 80/409 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV101193200; called by muse, mutect2, varscan2
- TEX15 | c.3394C>G p.P1132A (on ENST00000256246; = p.P1515A on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV56354747; called by muse, mutect2, varscan2
- TGM2 | c.657C>G p.Y219* | Nonsense Mutation (SNP) | VAF 66/544 reads (12%) | catalogued as rs1156389953; called by muse, mutect2, varscan2
- THEMIS | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs759978898, COSV64074923; called by muse, mutect2
- TJP2 | c.2417G>T p.W806L | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99602083; called by muse, mutect2, varscan2
- TLR4 | c.639C>A p.N213K (on ENST00000355622 / NM_138554.5; = p.N173K on NM_003266.4) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371871286, COSV100790704; called by muse, mutect2, varscan2
- TMEM132D | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 44/525 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs757165933, COSV70598638; called by muse, mutect2
- TMEM198 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 89/653 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs758782842; called by muse, mutect2, varscan2
- TMEM87B | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV51714696; called by muse, mutect2, varscan2
- TMPRSS9 | c.2765T>A p.L922Q (on ENST00000648592; = p.L888Q on NM_182973.2) | Missense Mutation (SNP) | VAF 62/366 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1301015719; called by muse, mutect2, varscan2
- TONSL | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV68048417; called by muse, mutect2
- TOPAZ1 | c.2368G>T p.G790C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV59069748; called by muse, mutect2, varscan2
- TPO | c.1690C>A p.L564I | Missense Mutation (SNP) | VAF 93/542 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM035087, COSV61104975; called by muse, mutect2, varscan2
- TPRX1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1341638803; called by muse, mutect2, varscan2
- TTLL5 | c.2812A>G p.T938A | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1004435343; called by muse, varscan2
- UNC79 | c.1984T>C p.S662P (on ENST00000393151 / NM_001346218.2; = p.S485P on NM_020818.5) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs866112389; called by muse, mutect2, varscan2
- VIT | c.1207G>A p.D403N (on ENST00000389975 / NM_001177969.1; = p.D418N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333868261; called by muse, mutect2, varscan2
- WDR89 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1459180736; called by muse, mutect2
- WSCD2 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 50/255 reads (20%) | catalogued as COSV54584835; called by muse, mutect2, varscan2
- ZFHX4 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs746502584, COSV50610942; called by muse, mutect2, varscan2
- ZIC4 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67172503; called by muse, varscan2
- ZNF385D | c.22+2T>A p.X8_splice | Splice Site (SNP) | VAF 17/159 reads (11%) | catalogued as COSV55778717; called by muse, mutect2, varscan2
- ZNF622 | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 28/473 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV58074669; called by muse, mutect2
- ZNF729 | c.2963G>T p.G988V | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99051640; called by muse, mutect2, varscan2
- ZPBP | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1395397866, COSV50427081; called by muse, mutect2, varscan2
- ABCA5 | c.2336C>A p.T779K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCF3 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ACTN2 | c.1554C>A p.H518Q | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ADCY10 | c.2687C>A p.S896Y | Missense Mutation (SNP) | VAF 81/567 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADCY4 | c.2509C>A p.L837M | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ADH7 | c.389C>G p.T130S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- AGPAT1 | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AIM2 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- AKNA | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- ALB | c.226del p.T76Hfs*65 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- ANO9 | c.1444A>G p.M482V | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ANP32A | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ARHGAP17 | c.782G>C p.S261T | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.138); called by muse, mutect2
- ARHGAP31 | c.2505G>C p.Q835H | Missense Mutation (SNP) | VAF 118/734 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF37 | c.1734G>T p.R578S | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB18 | c.1309G>C p.G437R | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASMT | c.957G>T p.M319I (on ENST00000381229; = p.M347I on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/661 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATP2B4 | c.2630G>T p.W877L | Missense Mutation (SNP) | VAF 71/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- B3GNT6 | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 62/379 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BCHE | c.1098C>G p.S366R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- BHMG1 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 86/603 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- BIN1 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 50/697 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- BIRC6 | c.6815T>C p.L2272P | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSG | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD11 | c.1547C>A p.A516D (on ENST00000280758 / NM_001018072.2; = p.A53D on NM_001017523.2) | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- C10orf120 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C16orf71 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); called by muse, mutect2
- C3 | c.3164A>G p.Q1055R | Missense Mutation (SNP) | VAF 103/736 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CA14 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACHD1 | c.1782+1G>T p.X594_splice | Splice Site (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- CACNA1S | c.4702C>A p.P1568T | Missense Mutation (SNP) | VAF 100/375 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CASQ1 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CAV3 | c.383T>G p.F128C | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CCDC30 | c.708G>T p.E236D (on ENST00000340612; = p.E193D on NM_001080850.3) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CD300E | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 63/448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH11 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- CDH22 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CDH23 | c.5332C>T p.Q1778* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | called by muse, varscan2
- CDH6 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CEP250 | c.4313A>T p.E1438V | Missense Mutation (SNP) | VAF 53/434 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CEP350 | c.6671A>G p.E2224G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CFAP300 | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); called by muse, mutect2
- CFAP46 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); called by muse, mutect2
- CFH | c.2344A>T p.R782* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- CHIA | c.1247G>T p.G416V (on ENST00000343320; = p.G308V on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CLEC4G | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, mutect2
- COBL | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- COL11A1 | c.2480C>A p.P827H | Missense Mutation (SNP) | VAF 70/507 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- COL12A1 | c.8834G>A p.G2945D | Missense Mutation (SNP) | VAF 36/846 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL20A1 | c.336G>A p.V112= | Splice Region (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2
- COL22A1 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- COL6A6 | c.3270C>A p.F1090L | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- CREB3L3 | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CROCC2 | c.4852A>T p.K1618* | Nonsense Mutation (SNP) | VAF 33/172 reads (19%) | called by muse, varscan2
- CRTC2 | c.227A>C p.Q76P | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRYBB1 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 132/683 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CSF1R | c.43T>A p.W15R | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CYP11A1 | c.1385G>C p.C462S | Missense Mutation (SNP) | VAF 43/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP2W1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DCHS1 | c.5352G>T p.Q1784H | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DDB2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 112/676 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DEFB116 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DGKB | c.2336C>G p.P779R | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLGAP1 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DLGAP2 | c.966del p.V323Wfs*37 | Frame Shift Del (DEL) | VAF 48/334 reads (14%) | called by mutect2, pindel, varscan2
- DLX1 | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- DNMT1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.306); called by muse, mutect2
- DOC2A | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DOCK3 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPP10 | c.496del p.X166_splice | Splice Site (DEL) | VAF 33/173 reads (19%) | called by mutect2, pindel, varscan2
- DPYSL3 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 48/216 reads (22%) | called by muse, mutect2, varscan2
- DRAXIN | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- DSG4 | c.48+2T>A p.X16_splice | Splice Site (SNP) | VAF 33/217 reads (15%) | called by muse, mutect2, varscan2
- DVL1 | c.1786G>T p.G596* (on ENST00000378888 / NM_001330311.2; = p.G571* on NM_004421.3) | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 39/201 reads (19%) | called by muse, mutect2, varscan2
- F13A1 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FAM135B | c.2525C>A p.P842H | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM197Y1 | n.419G>T | Splice Region (SNP) | VAF 64/231 reads (28%) | called by muse, mutect2, varscan2
- FAT4 | c.7162G>C p.A2388P | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBRSL1 | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXL7 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 139/888 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FEM1C | c.139A>C p.M47L | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FER1L6 | c.2133G>C p.E711D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- FMN2 | c.526A>G p.S176G | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- FMN2 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); called by muse, mutect2
- FOXB2 | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FOXG1 | c.1260C>A p.H420Q | Missense Mutation (SNP) | VAF 116/667 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FRY | c.636-1G>T p.X212_splice | Splice Site (SNP) | VAF 66/369 reads (18%) | called by muse, mutect2, varscan2
- GBE1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- GDF6 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- GMCL1 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, varscan2
- GOLGA8J | c.1893G>T p.R631S | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GRAMD1B | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK2 | c.558del p.E187Sfs*29 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- GRIK3 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- GTF2F1 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTF2IRD2 | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- GZMH | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HGF | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); called by muse, varscan2
- HHAT | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2
- HNRNPLL | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by mutect2, varscan2
- HSPG2 | c.10088A>T p.Y3363F | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HTR1B | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ICE1 | c.4102G>T p.E1368* | Nonsense Mutation (SNP) | VAF 18/551 reads (3%) | called by muse, mutect2
- IGHV1-58 | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 92/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGLJ3 | c.8G>T p.R3I | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- KASH5 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA4 | c.423C>A p.Y141* | Nonsense Mutation (SNP) | VAF 51/321 reads (16%) | called by muse, mutect2, varscan2
- KCNB1 | c.1527G>T p.Q509H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- KCNH7 | c.1850C>A p.A617E | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNJ12 | c.1072A>T p.S358C | Missense Mutation (SNP) | VAF 59/392 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KCNJ5 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 134/649 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNJ9 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 78/531 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNK9 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 65/353 reads (18%) | called by muse, mutect2, varscan2
- KIAA1522 | c.630G>C p.M210I (on ENST00000373480 / NM_001198972.2; = p.M269I on NM_020888.3) | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2026 | c.4600C>G p.P1534A | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.059); called by muse, mutect2
- KIF4A | c.1688A>T p.E563V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- KRT18 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 62/810 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.168); called by muse, mutect2
- KRTAP16-1 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- KRTAP9-1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- LCK | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LZTFL1 | c.670A>T p.K224* | Nonsense Mutation (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- MAGEB18 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAGED2 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- MBD5 | c.3895C>G p.R1299G | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MCOLN1 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 75/405 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MFSD2B | c.168A>G p.I56M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MPP4 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- MROH2B | c.159A>T p.Q53H | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MS4A2 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- MUC16 | c.43516C>G p.L14506V | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MUC16 | c.42094G>T p.D14032Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYH2 | c.2833A>T p.K945* | Nonsense Mutation (SNP) | VAF 66/403 reads (16%) | called by muse, mutect2, varscan2
- MYH7 | c.3440G>T p.S1147I | Missense Mutation (SNP) | VAF 58/680 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYOG | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NAALADL1 | c.308A>T p.E103V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NACC2 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 19/239 reads (8%) | called by muse, mutect2
- NAGK | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP14 | c.1702G>T p.G568* | Nonsense Mutation (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- NLRP14 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2
- NOL8 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2
- NPAP1 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- NPY1R | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- NRG3 | c.1481C>A p.T494K | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- NRXN1 | c.780C>A p.N260K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NSD1 | c.4445A>T p.Q1482L | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- NTSR2 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYAP1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR10S1 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR11H4 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR2T11 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- OR4A47 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR51A2 | c.765del p.I256Sfs*32 | Frame Shift Del (DEL) | VAF 31/182 reads (17%) | called by mutect2, varscan2
- OR51G2 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- OR5F1 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6B2 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 59/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- OTOA | c.1241G>T p.S414I (on ENST00000286149; = p.S400I on NM_144672.4) | Missense Mutation (SNP) | VAF 123/680 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- PARP9 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH11Y | c.3719C>A p.P1240H | Missense Mutation (SNP) | VAF 158/461 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PCDHB11 | c.665G>C p.R222T | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDE3B | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- PGM2L1 | c.749+1G>A p.X250_splice | Splice Site (SNP) | VAF 25/149 reads (17%) | called by muse, varscan2
- PHACTR3 | c.588C>A p.S196R | Missense Mutation (SNP) | VAF 150/475 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PHEX | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PIR | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD2L1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PLEKHG4 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- POM121L2 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- POSTN | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POU5F1B | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 98/501 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PRKAA2 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PRRC2C | c.3931A>T p.N1311Y (on ENST00000367742; = p.N1309Y on NM_015172.4) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PSMB5 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PTPN2 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PTPRN2 | c.2246G>A p.W749* | Nonsense Mutation (SNP) | VAF 58/433 reads (13%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.4730A>T p.D1577V | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- QSOX2 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAPGEF3 | c.749C>A p.S250Y (on ENST00000389212; = p.S208Y on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- REG3A | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- RFX1 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1L1 | c.6425_6426insAG p.P2143Gfs*7 | Frame Shift Ins (INS) | VAF 95/656 reads (14%) | called by mutect2, varscan2*
- RP1L1 | c.6423_6424del p.Q2142Afs*2 | Frame Shift Del (DEL) | VAF 94/691 reads (14%) | called by mutect2, varscan2*
- RP1L1 | c.3373C>A p.L1125M | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1L1 | c.2036A>T p.D679V | Missense Mutation (SNP) | VAF 99/554 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- RRM1 | c.1545G>T p.M515I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2
- RSPH4A | c.1321T>C p.W441R | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTF2 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2, varscan2
- RTL1 | c.2165A>G p.D722G | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RYK | c.1260del p.N421Ifs*11 (on ENST00000620660 / NM_001005861.2; = p.N418Ifs*11 on NM_002958.4) | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- SCEL | c.1387A>T p.S463C (on ENST00000349847 / NM_144777.3; = p.S443C on NM_003843.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, varscan2
- SCN7A | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.502); called by muse, varscan2
- SCUBE1 | c.1586A>G p.D529G | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SERPINA5 | c.1124C>A p.A375D | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SHISA9 | c.954del p.K319Rfs*9 | Frame Shift Del (DEL) | VAF 23/200 reads (12%) | called by mutect2, pindel, varscan2
- SIDT1 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, varscan2
- SLC13A1 | c.1786T>A p.*596Kext*1 | Nonstop Mutation (SNP) | VAF 26/120 reads (22%) | called by mutect2, varscan2
- SLC22A15 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SLC26A3 | c.637T>A p.F213I | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A7 | c.1211T>A p.L404Q | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A2 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 114/628 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A4 | c.1721G>T p.W574L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLFN5 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SMC5 | c.1298A>T p.K433M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SPATA31A1 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPATA31A6 | c.2717C>A p.P906H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- SPATA32 | c.1136C>A p.P379H | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SPEG | c.6638A>T p.D2213V | Missense Mutation (SNP) | VAF 66/299 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEG | c.7011C>A p.F2337L | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPTA1 | c.6762C>A p.H2254Q | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRP72 | c.963A>T p.E321D | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STK11IP | c.2690G>T p.C897F | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SUPT20H | c.1322A>C p.E441A (on ENST00000350612 / NM_001014286.3; = p.E442A on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SUSD2 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- TACR3 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TAS2R8 | c.712A>T p.T238S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- TBX18 | c.1476G>T p.M492I | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TDO2 | c.1109C>G p.T370R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- TEC | c.1775A>T p.N592I | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECPR2 | c.2595G>T p.K865N | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TERF1 | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TEX15 | c.86C>A p.T29N (on ENST00000638951; = p.T25N on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- TG | c.2875G>T p.V959L | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- THBD | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 74/401 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TOGARAM1 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM4 | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TRIM42 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- TRIM48 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSHZ3 | c.742A>T p.N248Y | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- UBTFL1 | c.374T>A p.M125K | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBTFL1 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNC79 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UPF3A | c.917A>T p.D306V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, varscan2
- URB1 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VEGFC | c.812-1G>T p.X271_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2
- VPS13B | c.5002C>G p.L1668V | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WFIKKN1 | c.487T>A p.W163R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- WIZ | c.5123G>T p.G1708V (on ENST00000673675 / NM_001371589.1; = p.G613V on NM_021241.3) | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- XPO7 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- ZAN | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 94/589 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZBTB14 | c.1136A>T p.H379L | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZBTB22 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMAT4 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF256 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- ZNF431 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZNF536 | c.3020C>G p.A1007G | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF610 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF644 | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF644 | c.2199G>T p.K733N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF696 | c.829A>T p.S277C | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF726 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF841 | c.1295A>G p.K432R (on ENST00000426391 / NM_001369830.1; = p.K548R on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ZNF99 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AATK | c.603G>T p.V201= (on ENST00000326724 / NM_001080395.3; = p.V98= on NM_004920.2) | Silent (SNP) | VAF 182/588 reads (31%) | called by muse, varscan2
- ABCC1 | c.999C>T p.A333= | Silent (SNP) | VAF 57/494 reads (12%) | called by muse, mutect2, varscan2
- ACAN | c.966C>A p.L322= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as COSV61368742; called by muse, mutect2, varscan2
- ACTR5 | c.1743G>A p.K581= | Silent (SNP) | VAF 57/434 reads (13%) | catalogued as rs1395260657, COSV99710012; called by muse, mutect2, varscan2
- ADAMTS20 | c.229C>A p.R77= | Silent (SNP) | VAF 52/421 reads (12%) | catalogued as rs1206429138, COSV67129951; called by muse, mutect2, varscan2
- ADAMTS5 | c.1099C>A p.R367= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- AGPS | c.1416G>A p.G472= | Silent (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- AHDC1 | c.2955G>A p.K985= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- AL121899.2 | c.2049C>A p.S683= | Silent (SNP) | VAF 55/319 reads (17%) | called by muse, mutect2, varscan2
- ALG10 | c.249T>C p.F83= | Silent (SNP) | VAF 63/448 reads (14%) | catalogued as rs769209909; called by muse, mutect2, varscan2
- AMER3 | c.1962C>T p.F654= | Silent (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- ANKEF1 | c.972G>T p.L324= | Silent (SNP) | VAF 38/244 reads (16%) | called by muse, mutect2, varscan2
- ANKRD30A | c.3087G>A p.L1029= (on ENST00000611781; = p.L973= on NM_052997.2) | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- APOBEC3C | c.60A>G p.Q20= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- APRT | c.357A>G p.P119= | Silent (SNP) | VAF 103/750 reads (14%) | called by muse, mutect2, varscan2
- ATP5PD | c.9G>T p.G3= | Silent (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- ATP8B4 | c.495T>A p.A165= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- B3GAT1 | c.456C>T p.Y152= | Silent (SNP) | VAF 73/375 reads (19%) | catalogued as rs766234152; called by muse, mutect2, varscan2
- BCL11A | c.105G>T p.P35= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as rs774400493, COSV59638556; called by muse, mutect2, varscan2
- BTBD2 | c.1009C>T p.L337= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs746702350; called by muse, mutect2, varscan2
- C1orf226 | c.666C>T p.S222= | Silent (SNP) | VAF 30/418 reads (7%) | catalogued as COSV63394922; called by muse, mutect2
- C5orf49 | c.411G>A p.K137= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs1361727669; called by muse, mutect2, varscan2
- CACNA1E | c.6057T>C p.R2019= (on ENST00000367573 / NM_001205293.3; = p.R1976= on NM_000721.4) | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2
- CALHM5 | c.774G>C p.T258= | Silent (SNP) | VAF 67/208 reads (32%) | called by muse, mutect2, varscan2
- CDK7 | c.93T>C p.D31= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- CDV3 | c.96G>T p.A32= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1241097247; called by muse, varscan2
- CNKSR2 | c.342G>A p.G114= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs780798514; called by muse, mutect2, varscan2
- CRX | c.810G>A p.K270= | Silent (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- CSMD1 | c.3690C>A p.I1230= (on ENST00000520002; = p.I1229= on NM_033225.6) | Silent (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- CSMD2 | c.522C>T p.H174= | Silent (SNP) | VAF 14/234 reads (6%) | catalogued as rs749023926, COSV53912233, COSV53919670; called by muse, mutect2
- CUL9 | c.3873G>T p.R1291= | Silent (SNP) | VAF 56/213 reads (26%) | called by muse, mutect2, varscan2
- DENND6B | c.579G>A p.Q193= | Silent (SNP) | VAF 26/340 reads (8%) | catalogued as COSV69807102; called by muse, mutect2
- DOCK3 | c.1983G>T p.L661= | Silent (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- DRAXIN | c.609C>A p.S203= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as COSV99610732; called by muse, mutect2, varscan2
- DVL1 | c.1785G>T p.A595= (on ENST00000378888 / NM_001330311.2; = p.A570= on NM_004421.3) | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV100229957, COSV59562438; called by muse, mutect2, varscan2
- DYSF | c.4548G>A p.E1516= | Silent (SNP) | VAF 98/496 reads (20%) | catalogued as COSV50531302; called by muse, mutect2, varscan2
- ECSIT | c.1227G>A p.E409= | Silent (SNP) | VAF 29/273 reads (11%) | called by muse, mutect2, varscan2
- EIF3L | c.1248C>T p.S416= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as rs1248847638; called by muse, mutect2, varscan2
- EYS | c.87G>C p.V29= | Silent (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- FAF1 | c.1413A>G p.T471= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, varscan2
- FAM135B | c.3501T>A p.P1167= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV52723926; called by muse, mutect2, varscan2
- FAM47C | c.2424G>T p.R808= | Silent (SNP) | VAF 79/248 reads (32%) | called by muse, mutect2, varscan2
- FLG | c.4830G>C p.R1610= | Silent (SNP) | VAF 68/548 reads (12%) | called by muse, mutect2, varscan2
- FMN2 | c.525C>A p.T175= | Silent (SNP) | VAF 34/434 reads (8%) | catalogued as COSV60418668; called by muse, mutect2
- GAL3ST3 | c.1110C>T p.P370= | Silent (SNP) | VAF 66/401 reads (16%) | catalogued as rs998694951, COSV61749508; called by muse, mutect2, varscan2
- GALNT7 | c.1032G>T p.G344= | Silent (SNP) | VAF 36/192 reads (19%) | called by muse, mutect2, varscan2
- GBP2 | c.387T>C p.N129= | Silent (SNP) | VAF 53/329 reads (16%) | catalogued as rs1281266773; called by muse, mutect2, varscan2
- GIMAP2 | c.78C>T p.I26= | Silent (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- GOT1L1 | c.888C>A p.V296= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2
- GREM2 | c.235C>A p.R79= | Silent (SNP) | VAF 38/330 reads (12%) | catalogued as rs149299291; called by muse, mutect2, varscan2
- GRIK4 | c.2064A>G p.Q688= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as rs1565465396; called by muse, mutect2, varscan2
- HHAT | c.1332G>T p.L444= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- HOXD1 | c.429C>A p.G143= | Silent (SNP) | VAF 70/455 reads (15%) | called by muse, mutect2, varscan2
- HSPA8 | c.1188C>G p.V396= | Silent (SNP) | VAF 37/267 reads (14%) | catalogued as COSV99914600; called by muse, mutect2, varscan2
- ICE1 | c.5214C>T p.H1738= | Silent (SNP) | VAF 103/316 reads (33%) | catalogued as rs375655407; called by muse, mutect2, varscan2
- IGF2R | c.4839G>T p.V1613= | Silent (SNP) | VAF 106/352 reads (30%) | catalogued as rs1319156714; called by muse, mutect2, varscan2
- IGHM | c.822C>G p.S274= | Silent (SNP) | VAF 96/976 reads (10%) | called by muse, mutect2
- IGKV1D-8 | c.33G>T p.G11= | Silent (SNP) | VAF 41/440 reads (9%) | catalogued as rs1432213722; called by muse, mutect2
- ILDR1 | c.81G>T p.T27= | Silent (SNP) | VAF 51/300 reads (17%) | called by muse, mutect2, varscan2
- IMMP2L | c.495A>G p.P165= | Silent (SNP) | VAF 78/315 reads (25%) | called by muse, mutect2, varscan2
- INTS3 | c.2337G>A p.V779= | Silent (SNP) | VAF 86/280 reads (31%) | called by muse, mutect2, varscan2
- ISG20L2 | c.657C>T p.P219= | Silent (SNP) | VAF 29/287 reads (10%) | catalogued as rs769564634; called by muse, mutect2
- JAKMIP2 | c.303A>G p.S101= | Silent (SNP) | VAF 61/270 reads (23%) | called by muse, mutect2, varscan2
- KCNA5 | c.1729C>A p.R577= | Silent (SNP) | VAF 58/286 reads (20%) | catalogued as COSV99363488; called by muse, mutect2, varscan2
- KCND3 | c.6G>T p.A2= | Silent (SNP) | VAF 90/571 reads (16%) | catalogued as COSV56181106; called by muse, mutect2, varscan2
- KCNIP4 | c.132A>G p.S44= | Silent (SNP) | VAF 24/388 reads (6%) | called by muse, mutect2
- KRT74 | c.1176G>T p.R392= | Silent (SNP) | VAF 101/557 reads (18%) | called by muse, mutect2, varscan2
- MAGEA6 | c.513C>A p.P171= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as rs1394846102; called by muse, mutect2, varscan2
- METTL22 | c.1086G>C p.L362= | Silent (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.42093G>T p.L14031= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2
- MYO18B | c.1371T>G p.G457= | Silent (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- NCOR2 | c.2124G>T p.S708= | Silent (SNP) | VAF 59/314 reads (19%) | called by muse, varscan2
- NLGN1 | c.1449G>T p.T483= | Silent (SNP) | VAF 29/382 reads (8%) | catalogued as rs370462767, COSV64338718; called by muse, mutect2
- NOL6 | c.915A>T p.T305= | Silent (SNP) | VAF 67/342 reads (20%) | called by muse, mutect2, varscan2
- OBP2A | c.282G>T p.G94= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- OLFM3 | c.183T>A p.P61= (on ENST00000338858 / NM_001288821.1; = p.P41= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/263 reads (17%) | called by muse, mutect2, varscan2
- OLFML2B | c.1935C>T p.V645= | Silent (SNP) | VAF 18/460 reads (4%) | called by muse, mutect2
- OR6Q1 | c.813C>T p.S271= | Silent (SNP) | VAF 30/327 reads (9%) | catalogued as rs1218609373; called by muse, mutect2
- PAG1 | c.1005A>G p.T335= | Silent (SNP) | VAF 37/215 reads (17%) | catalogued as rs769258692; called by muse, mutect2, varscan2
- PGLYRP3 | c.346C>T p.L116= | Silent (SNP) | VAF 58/327 reads (18%) | catalogued as COSV51950808; called by muse, mutect2, varscan2
- PIK3CG | c.1971G>A p.L657= | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, varscan2
- POLQ | c.7167C>A p.I2389= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV51761603; called by muse, mutect2, varscan2
- POTEI | c.2682C>T p.T894= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs779749619; called by mutect2, varscan2
- POU4F2 | c.426C>T p.Y142= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs1469911465, COSV55586925; called by muse, varscan2
- PPP4R3C | c.1344C>A p.R448= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- PRDM16 | c.2154G>T p.S718= | Silent (SNP) | VAF 40/317 reads (13%) | catalogued as COSV54591030, COSV99577932; called by muse, mutect2, varscan2
- PROSER1 | c.2040C>T p.S680= | Silent (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- PRRT4 | c.2580C>A p.R860= | Silent (SNP) | VAF 70/462 reads (15%) | called by muse, mutect2, varscan2
- PXDN | c.4080G>T p.G1360= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2
- RAB40AL | c.558G>T p.P186= | Silent (SNP) | VAF 124/273 reads (45%) | called by muse, mutect2, varscan2
- RAC3 | c.159G>A p.L53= | Silent (SNP) | VAF 59/508 reads (12%) | called by muse, mutect2, varscan2
- RASGRP3 | c.15C>T p.G5= | Silent (SNP) | VAF 18/171 reads (11%) | catalogued as COSV67821425; called by muse, mutect2, varscan2
- RHBDL3 | c.273C>T p.G91= | Silent (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
- RNF207 | c.966C>T p.G322= | Silent (SNP) | VAF 19/444 reads (4%) | called by muse, mutect2
- RPE65 | c.1461G>T p.L487= | Silent (SNP) | VAF 28/241 reads (12%) | catalogued as COSV99254397; called by muse, mutect2, varscan2
- RPL35 | c.204C>T p.N68= | Silent (SNP) | VAF 42/214 reads (20%) | catalogued as rs1361326908; called by muse, mutect2, varscan2
- RPRD2 | c.1077T>G p.P359= | Silent (SNP) | VAF 70/446 reads (16%) | called by muse, mutect2, varscan2
- SDHB | c.693G>T p.L231= | Silent (SNP) | VAF 72/603 reads (12%) | called by muse, mutect2, varscan2
- SETD3 | c.585G>C p.R195= | Silent (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- SGCD | c.234A>G p.L78= (on ENST00000435422 / NM_001128209.2; = p.L79= on NM_000337.5) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs759198194; called by muse, mutect2, varscan2
- SHANK1 | c.6297C>G p.T2099= | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- SI | c.3963C>T p.V1321= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as rs1334720926, COSV52279670; called by muse, mutect2, varscan2
- SLC1A3 | c.297T>A p.L99= | Silent (SNP) | VAF 51/366 reads (14%) | called by muse, mutect2, varscan2
- SLC2A9 | c.429C>T p.A143= | Silent (SNP) | VAF 94/523 reads (18%) | called by muse, mutect2, varscan2
- SLC45A1 | c.1527G>T p.V509= | Silent (SNP) | VAF 33/292 reads (11%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1659C>A p.A553= | Silent (SNP) | VAF 155/730 reads (21%) | called by muse, mutect2, varscan2
- SORCS1 | c.546C>A p.G182= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
- SPATA31D1 | c.2769T>C p.L923= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- SRA1 | c.9C>T p.R3= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV60365427; called by muse, mutect2, varscan2
- STK11IP | c.1797G>T p.S599= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV55246936; called by muse, mutect2, varscan2
- SV2B | c.1899A>G p.L633= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- TIAM2 | c.2574A>T p.V858= | Silent (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- TMEM47 | c.291G>A p.L97= | Silent (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- TOMM22 | c.30A>G p.A10= | Silent (SNP) | VAF 40/325 reads (12%) | catalogued as rs1242880678; called by muse, mutect2, varscan2
- TONSL | c.3216C>T p.L1072= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as rs371526843; called by muse, mutect2
- TRAPPC9 | c.3111G>T p.V1037= | Silent (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- TRPV2 | c.1668G>A p.L556= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs774134348; called by muse, mutect2, varscan2
- VAT1L | c.834C>A p.S278= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- VCPIP1 | c.186C>T p.A62= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs765764523; called by muse, mutect2, varscan2
- VPS35L | c.1581A>G p.A527= | Silent (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- VRTN | c.1260C>A p.P420= | Silent (SNP) | VAF 40/182 reads (22%) | called by muse, mutect2, varscan2
- WFS1 | c.1290G>T p.S430= | Silent (SNP) | VAF 56/319 reads (18%) | called by muse, mutect2, varscan2
- ZNF358 | c.309C>G p.P103= | Silent (SNP) | VAF 9/194 reads (5%) | catalogued as COSV51176775; called by muse, mutect2
- ZNF479 | c.1191T>A p.T397= | Silent (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- ZNF496 | c.213G>A p.L71= | Silent (SNP) | VAF 143/810 reads (18%) | called by muse, mutect2, varscan2
- ZNF638 | c.903A>G p.G301= | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as rs1247288353; called by mutect2, varscan2
- ZNF763 | c.201A>T p.I67= (on ENST00000358987 / NM_001367172.2; = p.I70= on NM_001012753.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- ZNF831 | c.3351G>T p.G1117= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100926090; called by muse, mutect2
- ZSCAN5B | c.1014G>T p.A338= | Silent (SNP) | VAF 94/407 reads (23%) | catalogued as COSV100627982; called by muse, mutect2, varscan2
- AC245047.1 | n.23dup | RNA (INS) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- ACO2 | c.1032+53G>T | Intron (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- AGBL1 | c.970-128C>T | Intron (SNP) | VAF 6/63 reads (10%) | catalogued as rs934696460; called by muse, mutect2, varscan2
- APOC2 | c.216-38G>A | Intron (SNP) | VAF 50/275 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916140 C>A | 5'Flank (SNP) | VAF 45/261 reads (17%) | called by muse, mutect2, varscan2
- ASPHD1 | c.-4G>T | 5'UTR (SNP) | VAF 31/149 reads (21%) | catalogued as COSV58103312; called by muse, mutect2, varscan2
- ATAD3B | c.645+19G>T | Intron (SNP) | VAF 66/284 reads (23%) | called by muse, mutect2, varscan2
- BAG4 | c.888+28A>C | Intron (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2
- BRD2 | c.29+162G>T | Intron (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- CATSPERZ | c.-16C>A | 5'UTR (SNP) | VAF 69/319 reads (22%) | called by muse, mutect2, varscan2
- CD320 | c.*22G>A | 3'UTR (SNP) | VAF 41/363 reads (11%) | catalogued as rs761560297; called by muse, mutect2, varscan2
- CHADL | c.*5G>T | 3'UTR (SNP) | VAF 44/334 reads (13%) | called by muse, mutect2, varscan2
- CORO7 | c.2685+61_2685+90del | Intron (DEL) | VAF 76/377 reads (20%) | called by mutect2, pindel
- DAZAP2 | chr12:51238806 A>G | 5'Flank (SNP) | VAF 32/226 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.3826C>A | RNA (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- EARS2 | chr16:23557425 A>T | 5'Flank (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- EML4 | c.1012-33G>T | Intron (SNP) | VAF 38/237 reads (16%) | called by muse, mutect2, varscan2
- ENTPD5 | chr14:73961405 C>T | 3'Flank (SNP) | VAF 105/951 reads (11%) | called by muse, mutect2, varscan2
- EPHA10 | c.1960+208G>T | Intron (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+6996G>T | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- FAM3C | c.*37A>T | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- GABRG3 | c.1123-1954dup | Intron (INS) | VAF 65/347 reads (19%) | called by mutect2, pindel, varscan2
- HNF4G | c.-23-3753G>T | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as COSV62967069; called by muse, mutect2, varscan2
- ITGA4 | c.*1869C>A | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as rs1246182055; called by muse, mutect2, varscan2
- KHSRP | chr19:6411811 C>A | 3'Flank (SNP) | VAF 26/229 reads (11%) | catalogued as rs760005205; called by muse, mutect2, varscan2
- KIRREL1 | c.*1964A>T | 3'UTR (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- LINC02740 | n.131T>A | RNA (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- MAP2 | c.455-1783G>T | Intron (SNP) | VAF 16/80 reads (20%) | called by muse, varscan2
- MEFV | c.910+2157C>G | Intron (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2
- MFSD14C | n.622G>T | RNA (SNP) | VAF 28/463 reads (6%) | catalogued as COSV64416070; called by muse, mutect2
- MIB1 | c.1830-9230A>T | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- MIR892B | n.32T>C | RNA (SNP) | VAF 34/99 reads (34%) | catalogued as rs1357565853; called by muse, mutect2, varscan2
- MUC5B | c.3455-49G>C | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- MYO7B | c.6249+87C>A | Intron (SNP) | VAF 68/600 reads (11%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.1279G>A | RNA (SNP) | VAF 55/411 reads (13%) | called by muse, mutect2, varscan2
- NDUFA10 | c.999+11G>A | Intron (SNP) | VAF 48/336 reads (14%) | called by mutect2, varscan2
- NLRP2 | c.2708+30G>T | Intron (SNP) | VAF 80/395 reads (20%) | catalogued as rs545190289; called by muse, mutect2, varscan2
- NOC2LP2 | n.812C>T | RNA (SNP) | VAF 80/446 reads (18%) | catalogued as rs1401917807; called by muse, mutect2, varscan2
- NOL4L | c.110-8608G>T | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110230G>T | Intron (SNP) | VAF 36/344 reads (10%) | called by muse, mutect2, varscan2
- NT5DC1 | c.-45G>T | 5'UTR (SNP) | VAF 91/272 reads (33%) | called by muse, mutect2, varscan2
- NXF5 | n.1246G>C | RNA (SNP) | VAF 46/140 reads (33%) | called by muse, mutect2, varscan2
- OR2M1P | n.441C>A | RNA (SNP) | VAF 66/375 reads (18%) | called by muse, mutect2, varscan2
- OR5E1P | n.427G>C | RNA (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- PAK3 | c.277-1639G>C | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- PALLD | c.1965-12857_1965-12838del | Intron (DEL) | VAF 44/272 reads (16%) | called by mutect2, pindel, varscan2
- PARVB | c.712+428A>C | Intron (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- PKP1 | c.1295+38A>T | Intron (SNP) | VAF 51/357 reads (14%) | called by muse, mutect2, varscan2
- PLCG1 | c.789+10G>T | Intron (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2
- PLP1 | c.697-43T>A | Intron (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- PPFIA4 | c.-300G>T | 5'UTR (SNP) | VAF 52/302 reads (17%) | called by muse, mutect2
- PTF1A | c.-33C>A | 5'UTR (SNP) | VAF 64/325 reads (20%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159319 C>T | 5'Flank (SNP) | VAF 25/87 reads (29%) | catalogued as rs200619814; called by muse, mutect2, varscan2
- RNU7-115P | chr17:64821829 G>A | 3'Flank (SNP) | VAF 61/490 reads (12%) | called by muse, mutect2, varscan2
- RPL34-DT | n.215C>T | RNA (SNP) | VAF 42/262 reads (16%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.9+301C>A | Intron (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- SH3BP2 | c.1406+13C>T | Intron (SNP) | VAF 52/650 reads (8%) | catalogued as rs1407252334; called by muse, mutect2
- SIGLEC6 | c.1012+39G>A | Intron (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2
- SLC12A3 | c.2924+14G>T | Intron (SNP) | VAF 73/457 reads (16%) | called by muse, mutect2, varscan2
- SLC2A8 | c.426+192A>T | Intron (SNP) | VAF 43/180 reads (24%) | called by muse, mutect2, varscan2
- SLC51A | c.-104C>A | 5'UTR (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
- SLC9B1P1 | n.635C>A | RNA (SNP) | VAF 8/38 reads (21%) | catalogued as rs754546543; called by muse, mutect2, varscan2
- SSPOP | n.9542C>T | RNA (SNP) | VAF 103/446 reads (23%) | called by muse, mutect2, varscan2
- SURF1 | c.-6G>T | 5'UTR (SNP) | VAF 26/231 reads (11%) | catalogued as rs1401348143; called by muse, mutect2, varscan2
- TMPO | c.279+40G>C | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs1380716996; called by muse, mutect2, varscan2
- TNPO2 | c.*2000G>T | 3'UTR (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2373C>A | Intron (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2
- TTN | c.10360+5164G>T | Intron (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
- TXK | c.-38C>G | 5'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- UQCRFS1 | c.-27G>T | 5'UTR (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- USH2A | c.-23G>A | 5'UTR (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- VIT | c.803-1590G>C | Intron (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2, varscan2
- VPS28 | c.37+31A>T | Intron (SNP) | VAF 41/255 reads (16%) | called by muse, mutect2, varscan2
- ZNF626 | c.226+299A>C | Intron (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99391816; called by muse, mutect2, varscan2
- ZP2 | c.-72C>A | 5'UTR (SNP) | VAF 30/131 reads (23%) | catalogued as COSV99559874; called by muse, mutect2, varscan2
